Gene-level copy-number profile of tumor specimen C3N-01081-03 from CPTAC case C3N-01081, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; Tumor grade: G3.
Specimen C3N-01081-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 857d2e6b-b8d7-471a-8396-e14224e632c4.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-01081-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,230 have no estimate.
https://portal.gdc.cancer.gov/files/f4eac177-9690-4533-a6fc-3f390e2bb194

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 23; copy number 1: 24; copy number 2: 4,351; copy number 3: 6,496; copy number 4: 34,176; copy number 5: 12,875; copy number 6: 335; copy number 7: 95; copy number 8: 11; copy number 10: 6; copy number 16: 1.

Homozygous deletions (total copy number 0; autosomes only): 22 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:117,493,515–117,495,006, 1 gene (within-gene range 0–5): AL157902.2.
- chr2:144,705,217–144,705,419, 1 gene (within-gene range 0–3): AC023128.2.
- chr2:195,003,711–195,026,370, 1 gene: AC010983.1.
- chr4:19,098,199–19,098,740, 1 gene: AC006840.1.
- chr4:19,181,814–19,181,856, 1 gene (within-gene range 0–3): RNA5SP157.
- chr4:70,226,124–70,235,252, 1 gene: FDCSP.
- chr5:100,153,672–100,153,779, 1 gene: RNU6-1119P.
- chr7:93,482,760–93,484,019, 2 genes (within-gene range 0–5): MIR653, MIR489.
- chr8:43,672,823–43,674,591, 2 genes: AC139365.2, AC139365.1.
- chr10:87,863,625–88,584,530, 7 genes (within-gene range 0–3): PTEN, AC063965.2, RPL11P3, AC063965.1, MED6P1, AL353149.1, RNLS.
- chr11:50,409,042–50,422,316, 1 gene: AC024405.1.
- chr11:87,847,259–88,045,608, 2 genes (within-gene range 0–4): AP000676.5, AP000676.4.
- chr18:29,048,620–29,048,719, 1 gene: RNU6-408P.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 7 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:18,333,726–18,412,264, 2 genes, copy number 10–16: CR383658.1, CR383658.2.
- chr21:12,999,676–13,120,807, 5 genes, copy number 10: AP001464.1, ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.

Autosomal genes at a single copy (total copy number 1): 24. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
